Somatic mutation profile of tumor specimen 8ab1a564-9a18-43bf-aee3-7fceb0 (aliquot 8ab1a564-9a18-43bf-aee3-7fceb0_D6) from CPTAC case 05BR042, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 40.0 years (14,599 days).
Specimen 8ab1a564-9a18-43bf-aee3-7fceb0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bc795c8-891b-4711-9e2e-ee9155026a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 9c427144-07ba-4190-bbe4-ec7faf (Blood Derived Normal), aliquot 9c427144-07ba-4190-bbe4-ec7faf_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec96394a-8459-41d7-981e-a0c160f16dc3

The open-access MAF lists 146 somatic variants for this specimen: 106 protein-altering or splice-affecting, 27 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 27, Frame Shift Del 11, Intron 5, Nonsense Mutation 4, RNA 4, Splice Site 3, Splice Region 2, Frame Shift Ins 2, 3'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTOGL | c.3081dup p.L1028Sfs*31 (on ENST00000547103; = p.L1019Sfs*31 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | catalogued as rs764178233; ClinVar: pathogenic; called by mutect2, varscan2
- ABCC8 | c.2053T>C p.Y685H | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV56847114; called by muse, mutect2, varscan2
- ACE | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 189/432 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV52023392; called by muse, mutect2, varscan2
- ACRBP | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 210/309 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565392693; called by muse, mutect2, varscan2
- ADA | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 101/423 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs761846813; called by muse, mutect2, varscan2
- AGO2 | c.878C>G p.T293R | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs777295780; called by muse, mutect2, varscan2
- ALOX5 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1458003454; called by mutect2, varscan2
- ANKRD31 | c.3883G>C p.V1295L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs1446619026; called by muse, varscan2
- ANKRD62 | c.2186A>G p.E729G | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1229970254; called by muse, mutect2, varscan2
- ARL13B | c.823A>G p.K275E (on ENST00000394222 / NM_001174150.2; = p.K168E on NM_144996.4) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs749623874; called by muse, mutect2, varscan2
- CACNA1A | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs1473069840; called by mutect2, varscan2
- CAMK1G | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs762140202; called by muse, mutect2
- CKAP2 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1485873824, COSV99318140; called by muse, mutect2, varscan2
- COL4A1 | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 44/441 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65427445; called by mutect2, varscan2
- DNAH7 | c.5261C>T p.P1754L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751216282; called by mutect2, varscan2
- GJA8 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 77/506 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.395); catalogued as COSV53789729; called by muse, mutect2, varscan2
- GRPEL2 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs769970165; called by muse, mutect2, varscan2
- IGF1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1404671399, COSV61031850; called by muse, mutect2, varscan2
- ITPRID1 | c.2666T>G p.M889R | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV60072282; called by muse, mutect2, varscan2
- KCNT2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV99651569; called by muse, mutect2, varscan2
- KDM5B | c.4292G>A p.R1431Q | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.151); catalogued as rs778451566, COSV52508114, COSV52511581; called by muse, mutect2, varscan2
- LONRF3 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as COSV59154362; called by muse, mutect2, varscan2
- MYH6 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs768924353, COSV100676153, COSV62451798; called by muse, mutect2, varscan2
- NCAN | c.3536C>T p.A1179V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs202059705; called by muse, mutect2, varscan2
- PACSIN2 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs752956842; called by muse, mutect2, varscan2
- PIK3CD | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs762697236; called by muse, mutect2, varscan2
- SCCPDH | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV100829721; called by muse, mutect2, varscan2
- SCN5A | c.2701G>C p.E901Q | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM100680; called by muse, mutect2, varscan2
- WDR97 | c.3346G>A p.A1116T | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1248395144; called by muse, mutect2, varscan2
- WNK2 | c.4678G>A p.V1560I (on ENST00000297954 / NM_001282394.1; = p.V1523I on NM_006648.3) | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs371709081; called by muse, mutect2, varscan2
- ZNF397 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1188556231; called by muse, mutect2, varscan2
- AC005833.1 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 83/150 reads (55%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACTN2 | c.1252T>C p.Y418H | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.187); called by muse, mutect2
- ADAM23 | c.2131G>T p.G711* | Nonsense Mutation (SNP) | VAF 75/200 reads (38%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.989C>G p.P330R | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AEBP1 | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 146/485 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- AMMECR1 | c.632_647del p.P211Qfs*26 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- ANO4 | c.2129T>G p.F710C (on ENST00000392977 / NM_001286615.2; = p.F675C on NM_178826.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ARHGAP33 | c.3044C>G p.P1015R | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CACNA1E | c.4657A>G p.S1553G | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH22 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CEBPZ | c.1881+1del p.X627_splice | Splice Site (DEL) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- CEPT1 | c.951T>G p.C317W | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COPA | c.927C>T p.G309= | Splice Region (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- COTL1 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- CPEB1 | c.1204C>T p.P402S (on ENST00000617958; = p.P342S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- DECR2 | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DGKQ | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, varscan2
- DHX16 | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EI24 | c.674-23_701del p.X225_splice | Splice Site (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel
- ELOVL2 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERG | c.1060G>A p.V354M (on ENST00000398919 / NM_001243428.1; = p.V330M on NM_004449.4) | Missense Mutation (SNP) | VAF 105/300 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETV3L | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2
- FAM193A | c.2492A>G p.K831R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- FUT6 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FZD2 | c.728T>C p.F243S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GFRAL | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GPATCH8 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- IQCE | c.618del p.D207Mfs*9 | Frame Shift Del (DEL) | VAF 72/266 reads (27%) | called by mutect2, pindel, varscan2
- ITGA3 | c.2093A>T p.E698V | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2263G>C p.D755H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.971); called by muse, mutect2
- KCNH1 | c.353A>C p.N118T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNS1 | c.120C>A p.D40E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.5513A>C p.D1838A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL38 | c.1490A>C p.Q497P | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2
- KRT19 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- LOXL3 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRIG1 | c.2486_2490del p.N829Rfs*2 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | called by mutect2, pindel
- MACF1 | c.14443_14456del p.D4815Pfs*23 (on ENST00000372915; = p.D2748Pfs*23 on NM_012090.5) | Frame Shift Del (DEL) | VAF 44/152 reads (29%) | called by mutect2, pindel, varscan2
- MAP4 | c.2192C>A p.T731N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MBOAT7 | c.1250T>C p.L417P | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- METAP2 | c.1200del p.K400Nfs*4 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, varscan2
- MGAT5B | c.1435G>A p.E479K (on ENST00000569840 / NM_001199172.2; = p.E477K on NM_144677.3) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MSANTD2 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MYO18B | c.682A>C p.T228P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NFX1 | c.2510G>C p.C837S | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51B5 | c.328T>G p.S110A | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PC | c.2782_2798del p.R928Sfs*33 | Frame Shift Del (DEL) | VAF 104/403 reads (26%) | called by mutect2, pindel, varscan2
- PFKFB3 | c.632_644del p.S211* | Frame Shift Del (DEL) | VAF 67/305 reads (22%) | called by mutect2, pindel, varscan2
- PIGO | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PITPNM2 | c.2668_2669insT p.A890Vfs*16 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- PNPLA1 | c.505-4A>G | Splice Region (SNP) | VAF 73/252 reads (29%) | called by muse, mutect2, varscan2
- PPFIA2 | c.3752C>G p.T1251S | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRMT9 | c.1678C>T p.H560Y | Missense Mutation (SNP) | VAF 153/375 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRSS23 | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- PTGDR2 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RALY | c.341T>C p.F114S | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SERPINA3 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2
- SFXN2 | c.847T>G p.C283G | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIM2 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCD2 | c.915T>A p.D305E | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TAF4B | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TARM1 | c.622C>T p.Q208* (on ENST00000616041 / NM_001330650.1; = p.Q200* on NM_001135686.3) | Nonsense Mutation (SNP) | VAF 63/178 reads (35%) | called by muse, mutect2, varscan2
- TBX19 | c.992_998del p.T331Mfs*56 | Frame Shift Del (DEL) | VAF 62/401 reads (15%) | called by mutect2, pindel, varscan2
- TCTE1 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TDRKH | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- THUMPD2 | c.725C>G p.A242G | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- TMTC2 | c.1288_1295del p.G430Pfs*8 | Frame Shift Del (DEL) | VAF 71/243 reads (29%) | called by mutect2, pindel, varscan2
- TRPC3 | c.2518A>C p.S840R (on ENST00000379645 / NM_001366479.2; = p.S767R on NM_003305.2) | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2
- UCN3 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VTN | c.724_725del p.N242Yfs*3 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- WDR43 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWC2 | c.3518_3520del p.K1173del | In Frame Del (DEL) | VAF 6/68 reads (9%) | called by pindel, varscan2
- ZEB2 | c.439_454del p.Y147Nfs*60 | Frame Shift Del (DEL) | VAF 32/204 reads (16%) | called by mutect2, varscan2
- ZNF408 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 135/559 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ZNF568 | c.77-1G>C p.X26_splice | Splice Site (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- ACTRT2 | c.522C>A p.S174= | Silent (SNP) | VAF 93/424 reads (22%) | called by muse, mutect2, varscan2
- ANKRD44 | c.786T>G p.G262= | Silent (SNP) | VAF 71/394 reads (18%) | called by muse, mutect2, varscan2
- ANTXRL | c.1218G>T p.P406= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- FCSK | c.186C>T p.N62= | Silent (SNP) | VAF 38/223 reads (17%) | catalogued as rs748587910, COSV55368986; called by muse, mutect2, varscan2
- FERMT1 | c.171A>T p.S57= | Silent (SNP) | VAF 115/250 reads (46%) | called by muse, mutect2, varscan2
- H2BC21 | c.165C>A p.I55= | Silent (SNP) | VAF 14/303 reads (5%) | called by muse, mutect2
- HSD3B1 | c.825G>A p.E275= | Silent (SNP) | VAF 167/478 reads (35%) | called by muse, mutect2, varscan2
- HSPG2 | c.1392G>A p.L464= | Silent (SNP) | VAF 74/590 reads (13%) | called by mutect2, varscan2
- IGFBPL1 | c.660T>A p.S220= | Silent (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- KALRN | c.1434A>G p.L478= | Silent (SNP) | VAF 43/294 reads (15%) | called by muse, mutect2, varscan2
- KBTBD4 | c.969G>A p.L323= | Silent (SNP) | VAF 48/510 reads (9%) | catalogued as rs1298164888; called by muse, mutect2
- KIAA0753 | c.2736C>T p.I912= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV63818854; called by muse, mutect2, varscan2
- LONRF3 | c.621G>T p.G207= | Silent (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- MAGED1 | c.669T>A p.G223= | Silent (SNP) | VAF 61/158 reads (39%) | called by muse, mutect2, varscan2
- NCOA2 | c.345G>C p.L115= | Silent (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.10167C>G p.A3389= | Silent (SNP) | VAF 93/335 reads (28%) | called by muse, mutect2, varscan2
- OR2Z1 | c.288T>A p.G96= | Silent (SNP) | VAF 122/424 reads (29%) | called by muse, mutect2, varscan2
- PNPLA2 | c.378T>C p.N126= | Silent (SNP) | VAF 180/349 reads (52%) | catalogued as rs1386170962; called by muse, mutect2, varscan2
- PYM1 | c.495A>G p.E165= | Silent (SNP) | VAF 29/206 reads (14%) | called by muse, mutect2, varscan2
- RFPL1 | c.340C>T p.L114= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs745818040, COSV62977450; called by muse, mutect2
- SAMD1 | c.192G>T p.P64= | Silent (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- SMAD3 | c.303C>T p.H101= | Silent (SNP) | VAF 187/447 reads (42%) | catalogued as rs762889441; called by mutect2, varscan2
- STRA6 | c.1350C>A p.A450= | Silent (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- STX11 | c.102G>A p.V34= | Silent (SNP) | VAF 52/521 reads (10%) | catalogued as rs749122183; called by muse, mutect2
- SYT15 | c.882C>G p.R294= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- USH2A | c.12882T>C p.I4294= | Silent (SNP) | VAF 22/526 reads (4%) | called by muse, mutect2
- WDR75 | c.2367C>T p.T789= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs535803074; called by muse, mutect2, varscan2
- AAK1 | c.*10376A>G | 3'UTR (SNP) | VAF 11/248 reads (4%) | catalogued as rs1283439893; called by muse, mutect2
- AC068633.1 | n.145C>T | RNA (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.192+779C>G | Intron (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.-61C>A | 5'UTR (SNP) | VAF 56/315 reads (18%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65181332 del CTGCCGTTTGCTGA | 5'Flank (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2
- CD3E | c.352+38T>C | Intron (SNP) | VAF 90/203 reads (44%) | catalogued as rs754296459; called by muse, mutect2, varscan2
- DBNL | c.753+23G>C | Intron (SNP) | VAF 42/137 reads (31%) | catalogued as rs1342395126; called by muse, mutect2, varscan2
- FAM90A20P | n.627C>T | RNA (SNP) | VAF 137/598 reads (23%) | catalogued as rs779343326; called by muse, mutect2, varscan2
- GABRA1 | c.-16+578del | Intron (DEL) | VAF 21/89 reads (24%) | catalogued as rs778778021; called by mutect2, pindel, varscan2
- OR2T27 | chr1:248649919 del T | 3'Flank (DEL) | VAF 37/202 reads (18%) | called by mutect2, pindel, varscan2
- SUSD1 | c.1172-869C>T | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- TMEM105 | n.542C>T | RNA (SNP) | VAF 42/235 reads (18%) | called by muse, mutect2, varscan2
- TMEM105 | n.541G>A | RNA (SNP) | VAF 42/234 reads (18%) | catalogued as rs904512450; called by muse, mutect2, varscan2
